Somatic mutation profile of tumor specimen TCGA-BT-A2LD-01A (aliquot TCGA-BT-A2LD-01A-12D-A20D-08) from TCGA case TCGA-BT-A2LD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.5 years (28,673 days).
Specimen TCGA-BT-A2LD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6103c0a-2e2e-4613-99e0-f492a3e1faa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A2LD-10A (Blood Derived Normal), aliquot TCGA-BT-A2LD-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0939c8ed-132a-4c80-af0d-51993bd88f16

The open-access MAF lists 101 somatic variants for this specimen: 73 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 27, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 42/131 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69042031, COSV69042523, COSV69043220; called by muse, mutect2, varscan2
- SMARCA4 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60795621; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 63/103 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1338810222, COSV57168669, COSV57169583; called by muse, mutect2
- AKAP6 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV55225843; called by muse, mutect2, varscan2
- ANO8 | c.3209G>A p.G1070D | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.11); catalogued as COSV50192214; called by muse, mutect2, varscan2
- ASXL1 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100040940, COSV60116235; called by muse, mutect2
- BLOC1S6 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV55036065; called by muse, mutect2, varscan2
- C3orf20 | c.2379T>G p.F793L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV53784055, COSV53787923; called by muse, mutect2
- CD22 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV50061184; called by muse, mutect2, varscan2
- CLIC1 | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV65384268; called by muse, mutect2, varscan2
- CNOT10 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV59394036; called by muse, mutect2, varscan2
- CNTNAP2 | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1345397568, COSV62185171; called by muse, mutect2, varscan2
- COPG1 | c.947T>C p.M316T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as COSV59115813; called by muse, mutect2
- CSMD3 | c.9937G>T p.V3313F (on ENST00000297405 / NM_001363185.1; = p.V3144F on NM_052900.3) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs774163140, COSV52267054; called by muse, mutect2, varscan2
- CSNK1G1 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV57312620; called by muse, mutect2, varscan2
- CXXC1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs771983953, COSV53276191; called by muse, mutect2, varscan2
- DCAF1 | c.2801G>A p.R934Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.154); catalogued as rs114108730, COSV60045468; called by muse, mutect2, varscan2
- DMRTB1 | c.645C>A p.H215Q | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as COSV65113699; called by muse, mutect2
- DOCK1 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV54752413; called by muse, mutect2
- FAT3 | c.3796C>T p.R1266C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529470178, COSV53153014; called by muse, mutect2
- FAT3 | c.5894C>T p.T1965I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as COSV53153039; called by muse, mutect2, varscan2
- FGFR4 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs750637669, COSV52803533; called by muse, mutect2, varscan2
- FNDC1 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV51930790; called by muse, mutect2, varscan2
- FNDC3A | c.3219G>T p.M1073I (on ENST00000492622 / NM_001079673.2; = p.M1017I on NM_014923.5) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV68134347; called by muse, mutect2, varscan2
- GPC5 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV65617738; called by muse, mutect2, varscan2
- GRIN2A | c.2115G>C p.M705I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58049418; called by muse, mutect2, varscan2
- GUCY2D | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs764439180, COSV54697817; called by muse, mutect2
- HEATR1 | c.5605G>A p.A1869T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs375609616; called by muse, mutect2
- HMCN1 | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV54925939; called by muse, mutect2, varscan2
- JAG1 | c.3065G>T p.R1022L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54760790; called by muse, mutect2, varscan2
- KALRN | c.2357A>G p.D786G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53774993; called by muse, mutect2, varscan2
- KIF16B | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV61711270; called by muse, mutect2
- KIF1A | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs763524814, COSV57484109; called by muse, mutect2, varscan2
- LRRC49 | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV53013647; called by muse, mutect2, varscan2
- MBTPS2 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV63412139; called by muse, mutect2, varscan2
- MUC17 | c.4767G>C p.E1589D | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60298045; called by muse, mutect2
- NECTIN1 | c.851+1G>A p.X284_splice | Splice Site (SNP) | VAF 14/84 reads (17%) | catalogued as rs889179187, CS097581, COSV50602279; called by muse, mutect2, varscan2
- NOS3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374834315; called by muse, mutect2, varscan2
- NR1I3 | c.761G>A p.R254Q (on ENST00000367982 / NM_001077480.3; = p.R250Q on NM_005122.5) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs753430504, COSV63467261; called by muse, mutect2, varscan2
- OTUD7B | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100967675; called by muse, mutect2
- PCSK5 | c.4196G>A p.G1399E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs916392963, COSV70451666; called by muse, mutect2, varscan2
- PPIP5K2 | c.1933G>A p.G645R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV58608262; called by muse, mutect2, varscan2
- PROKR1 | c.910A>C p.T304P | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV58138651; called by muse, mutect2
- PRR5 | c.572G>A p.R191K (on ENST00000336985 / NM_181333.4; = p.R182K on NM_015366.4) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV50062732; called by muse, mutect2
- RHBDF1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs745876843, CM142572, COSV51957120; called by muse, mutect2, varscan2
- RNF40 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV61216034; called by muse, varscan2
- RYR2 | c.5937T>G p.F1979L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV63666234; called by muse, mutect2
- SAA2 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV56777640, COSV56777789; called by muse, mutect2
- SIGLEC12 | c.974C>T p.S325L (on ENST00000291707 / NM_053003.4; = p.S207L on NM_033329.2) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs149053840; called by muse, mutect2, varscan2
- SLC4A10 | c.2973G>A p.M991I (on ENST00000446997 / NM_001354461.2; = p.M961I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55792146; called by muse, mutect2, varscan2
- SMAD7 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766483132, COSV50991205; called by muse, mutect2, varscan2
- SNX29 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1212712170, COSV60066997; called by muse, mutect2, varscan2
- SRCAP | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV52669103; called by muse, mutect2, varscan2
- STXBP5L | c.3413G>A p.R1138H | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs778813739, COSV56497930; called by muse, mutect2, varscan2
- TRIM46 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as rs753412148, COSV58111151; called by muse, mutect2, varscan2
- TTN | c.91090C>A p.P30364T (on ENST00000591111; = p.P22940T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | PolyPhen probably damaging (0.951); catalogued as COSV60239238; called by muse, mutect2, varscan2
- TUBGCP3 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs1339085041, COSV56184872; called by muse, mutect2
- UGT3A1 | c.920A>G p.H307R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1391339561, COSV57101213; called by muse, mutect2
- VPS9D1 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs952281021, COSV66995025; called by muse, mutect2, varscan2
- WBP1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201448542, COSV51970645; called by muse, mutect2, varscan2
- ZFP82 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67566191; called by muse, varscan2
- ZNF471 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV57290724, COSV57292730; called by muse, mutect2, varscan2
- ZNF704 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59926727; called by muse, mutect2
- ZNF804A | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV56456895, COSV56462599; called by muse, mutect2, varscan2
- ZNF84 | c.1889A>G p.N630S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1016194677; called by muse, mutect2
- ZNFX1 | c.5575G>A p.D1859N | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs764553505, COSV65600394; called by muse, mutect2, varscan2
- ARID1A | c.1498dup p.Y500Lfs*123 | Frame Shift Ins (INS) | VAF 187/566 reads (33%) | called by mutect2, pindel, varscan2
- FAM104A | c.279_281del p.R93del | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- FOXA1 | c.131dup p.M44Ifs*183 | Frame Shift Ins (INS) | VAF 16/107 reads (15%) | called by mutect2, pindel, varscan2
- KDM6A | c.349del p.Q117Rfs*63 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- MEOX2 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- TTN | c.19230G>A p.M6410I (on ENST00000591111; = p.M5483I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | PolyPhen benign (0); called by muse, mutect2
- AMBP | c.72G>A p.T24= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs750913733, COSV54324996; called by muse, mutect2
- ANKRD50 | c.2472A>G p.Q824= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1276803342, COSV72386058; called by muse, mutect2
- BAAT | c.1143G>A p.R381= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- CCR5 | c.864G>A p.T288= | Silent (SNP) | VAF 28/455 reads (6%) | catalogued as rs372879037; called by muse, mutect2
- CHAC1 | c.387T>C p.Y129= | Silent (SNP) | VAF 30/273 reads (11%) | catalogued as COSV71436224; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.144C>T p.I48= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV50451219; called by muse, mutect2, varscan2
- CNTN5 | c.2997A>G p.P999= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV54340314; called by muse, mutect2, varscan2
- CTHRC1 | c.708C>T p.I236= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs754161630, COSV57716058; called by muse, varscan2
- DOK6 | c.474G>A p.Q158= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV66935286; called by muse, mutect2, varscan2
- ECPAS | c.1947C>T p.I649= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV52204163; called by muse, mutect2, varscan2
- IGDCC3 | c.963G>A p.Q321= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100031379, COSV60079131; called by muse, mutect2
- JADE2 | c.1767C>T p.D589= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs779020941, COSV50925320; called by muse, mutect2, varscan2
- KCNH1 | c.2969G>A p.*990= (on ENST00000271751 / NM_172362.3; = p.*963= on NM_002238.4) | Silent (SNP) | VAF 12/213 reads (6%) | called by muse, mutect2
- NCAM2 | c.702C>A p.A234= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV53093516; called by muse, mutect2
- NOL9 | c.2067G>A p.E689= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV66626693; called by muse, mutect2
- PLXNC1 | c.2994G>A p.E998= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV51580530; called by muse, mutect2, varscan2
- PPP1R9A | c.2982T>C p.S994= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV56904385; called by muse, mutect2, varscan2
- PPP2R2C | c.24G>A p.R8= | Silent (SNP) | VAF 35/308 reads (11%) | catalogued as COSV58671655; called by muse, mutect2, varscan2
- PRRC2C | c.501A>G p.G167= (on ENST00000367742; = p.G165= on NM_015172.4) | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV58910377; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1431C>T p.H477= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV52864391; called by muse, mutect2, varscan2
- REV3L | c.6411A>G p.K2137= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV62621834; called by muse, mutect2, varscan2
- SBDS | c.213C>T p.L71= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as COSV55888235; called by muse, mutect2
- SENP7 | c.96A>G p.R32= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV58616175; called by muse, mutect2, varscan2
- SLC2A14 | c.1293C>T p.C431= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as rs780264514, COSV61587929; called by muse, mutect2
- SRCAP | c.739C>T p.L247= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV52678168; called by muse, mutect2, varscan2
- TMEM132D | c.168G>A p.A56= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs752280349, COSV70606335, COSV70613554; called by muse, mutect2, varscan2
- ZNF142 | c.1179C>T p.C393= (on ENST00000411696 / NM_001379660.1; = p.C193= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV68744890; called by muse, mutect2, varscan2
- NR1I2 | c.-23+517C>A | Intron (SNP) | VAF 8/98 reads (8%) | catalogued as COSV61979258; called by muse, mutect2
